Surgical pathology report (de-identified scan), TCGA case TCGA-B0-5080, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-5080-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: RIGHT KIDNEY AND PROXIMAL URETER, LAPAROSCOPIC NEPHRECTOMY -

- A. RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL AND FOCAL GRANULAR CELL) TYPE, PREDOMINANTLY FUHRMAN NUCLEAR GRADE 2/4, WITH FOCAL AREAS OF FUHRMAN NUCLEAR GRADE 3/4, 9 CM. CARCINOMA EPICENTER IS IN THE LOWER POLE OF THE RIGHT KIDNEY. FOCAL EXTRARENAL EXTENSION INTO RENAL SINUS ADIPOSE TISSUE IS IDENTIFIED (SLIDE 1I). MULTIPLE INTRARENAL DEPOSITS OF CONVENTIONAL RENAL CELL CARCINOMA (0.1 CM - 1 CM.) MOST LIKELY REPRESENTING INTRARENAL SATELLITE METASTASES (SLIDES 1F, 1G). NO TUMOR THROMBUS IS IDENTIFIED IN LARGE RENAL VEINS. ALL SURGICAL RESECTION MARGINS ARE BENIGN. PATHOLOGIC STAGE: T3a, NX, M1 (see microscopic description, diagnosis comment and part 2).
- B. NON-NEOPLASTIC KIDNEY WITH NO SIGNIFICANT HISTOLOGIC ABNORMALITY.
- C. SEGMENT OF BENIGN URETER, RENAL ARTERY AND RENAL VEIN.

PART 2: RIGHT ADRENAL GLAND, ADRENALECTOMY -

METASTATIC RENAL CELL CARCINOMA WITH THE LARGEST METASTATIC DEPOSIT MEASURING 2.5 CM. METASTATIC CARCINOMA APPEARS CONFINED TO THE ADRENAL GLAND. SURGICAL RESECTION MARGINS ARE BENIGN.

Source: NCI Genomic Data Commons file fd351dd9-b5ed-427f-a2d2-2c0272396920 (TCGA-B0-5080.E5EE3B20-2DAA-4AB8-AA36-8539DEC95F16.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).